Gene-level copy-number profile of tumor specimen TCGA-D7-8578-01A from TCGA case TCGA-D7-8578, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.9 years (26,620 days).
Specimen TCGA-D7-8578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.88e48ee6-2afb-4efc-a139-13037216dd60.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-8578-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05a40bf8-c737-4954-8294-fe41b041b628

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 544; copy number 2: 9,086; copy number 3: 11,797; copy number 4: 31,257; copy number 5: 648; copy number 6: 5,488; copy number 7: 175; copy number 9: 84; copy number 10: 621; copy number 13: 70; copy number 17: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-8578-01A-21D-2338-01): tumor purity 0.35, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 825 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:958,887–1,712,344, 26 genes, copy number 13 (within-gene range 3–13): DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP.
- chr11:45,387,215–45,513,802, 2 genes, copy number 10 (within-gene range 2–10): AC103855.3, AC018716.2.
- chr11:45,486,867–46,239,267, 24 genes, copy number 10: AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1.
- chr17:997,129–1,777,565, 30 genes, copy number 9 (within-gene range 3–9): TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1.
- chr20:35,002,404–64,313,132, 743 genes, copy number 9–17 (within-gene range 7–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 544. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
